Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6CX, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6CX-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localisation: L temporal

Diagnosis: Astrocitoma (grade II WHO)

Name of Pathologist:

ICD-O-3
Astrocytoma NOS
9400/3
Site CGCF
4 Brain, supratentorial NOS
C71.0
path L Brain, temporal lobe
C71.2
JW 5/16/13

Source: NCI Genomic Data Commons file 0729510a-f0c7-4baf-b94d-a50d72224fba (TCGA-QH-A6CX.FD9CC0AD-0EDC-4B6F-BE5E-ACBB0154EA3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).